Somatic mutation profile of tumor specimen TARGET-10-PARWNW-09A (aliquot TARGET-10-PARWNW-09A-01D) from TARGET case TARGET-10-PARWNW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.0 years (4,366 days).
Specimen TARGET-10-PARWNW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86c3c78a-fea9-44d5-bf27-94f119879e24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARWNW-10A (Blood Derived Normal), aliquot TARGET-10-PARWNW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a6b6b5d-4164-431a-b00c-89e88a835e93

The open-access MAF lists 29 somatic variants for this specimen: 25 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Intron 3, Nonsense Mutation 2, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSPH1 | c.311G>T p.C104F | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61223348; called by muse, mutect2, varscan2
- CYSLTR1 | c.915G>T p.R305S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV100964725; called by muse, mutect2, varscan2
- DYSF | c.6059G>A p.R2020H | Missense Mutation (SNP) | VAF 73/148 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763205852, COSV50468163; called by muse, mutect2, varscan2
- MROH9 | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205122746; called by muse, mutect2
- MRPS24 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs745460348, COSV58182332; called by muse, varscan2
- NFATC2 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as rs781647966, COSV65358003; called by muse, mutect2, varscan2
- NOTCH1 | c.7246C>T p.Q2416* | Nonsense Mutation (SNP) | VAF 68/166 reads (41%) | catalogued as rs1564567815, COSV53067965; called by mutect2, varscan2
- NOTCH1 | c.5033T>A p.L1678Q | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- OR8H2 | c.878G>C p.R293T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV57946072, COSV57946685; called by muse, mutect2, varscan2
- PLXNB2 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV100833817; called by muse, mutect2
- PTPRZ1 | c.576T>G p.D192E | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV66440843; called by muse, mutect2, varscan2
- RASAL2 | c.437C>A p.P146Q | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV62722156; called by muse, mutect2
- RESF1 | c.541C>A p.Q181K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV100440482; called by muse, mutect2
- SERPINA11 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV58242971; called by muse, varscan2
- SLITRK4 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs371255197, COSV62023616; called by muse, mutect2, varscan2
- TARS2 | c.1922T>C p.L641P | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60873847; called by muse, mutect2, varscan2
- CASC3 | c.1651C>A p.L551M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.045); called by muse, mutect2
- FBLN7 | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2
- FLG | c.10247A>G p.E3416G | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.913); called by muse, mutect2
- HNRNPH1 | c.935_936insGATGCGT p.N313Mfs*10 | Frame Shift Ins (INS) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- KBTBD11 | c.516C>A p.D172E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.04); called by muse, mutect2
- KCNN2 | c.239C>A p.A80E (on ENST00000264773; = p.A292E on NM_021614.4) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.184); called by muse, mutect2
- PIF1 | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- TLL2 | c.1052G>T p.C351F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UXS1 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- DCAF13 | c.1062T>C p.A354= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- AC008758.1 | c.3+37502G>T | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- RBM24 | c.348-1702A>G | Intron (SNP) | VAF 35/98 reads (36%) | called by muse, mutect2, varscan2
- TTYH1 | c.126+1090C>A | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
